Somatic mutation profile of tumor specimen TCGA-MP-A4TK-01A (aliquot TCGA-MP-A4TK-01A-11D-A24P-08) from TCGA case TCGA-MP-A4TK, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 56.3 years (20,581 days).
Specimen TCGA-MP-A4TK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25578ff6-f477-4506-89ab-52018cd75aef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MP-A4TK-10A (Blood Derived Normal), aliquot TCGA-MP-A4TK-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c212ca6c-4b04-40fb-ab4c-203f544cd337

The open-access MAF lists 379 somatic variants for this specimen: 286 protein-altering or splice-affecting, 85 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 245, Silent 85, Nonsense Mutation 19, Splice Site 11, Frame Shift Del 8, Intron 4, RNA 3, In Frame Del 2, Frame Shift Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 29/67 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AARS1 | c.1993-1G>A p.X665_splice | Splice Site (SNP) | VAF 3/14 reads (21%) | catalogued as rs1037071978, COSV99933733; called by muse, mutect2
- ABCA9 | c.4110G>T p.E1370D | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV100383108, COSV100383407; called by muse, mutect2, varscan2
- ABCC2 | c.2747+2T>C p.X916_splice | Splice Site (SNP) | VAF 18/106 reads (17%) | catalogued as rs778995579, COSV100966677; called by muse, mutect2, varscan2
- ABCG1 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100494458; called by muse, mutect2, varscan2
- ACAP2 | c.2108C>G p.T703S | Missense Mutation (SNP) | VAF 5/117 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.011); catalogued as COSV58752376; called by muse, mutect2
- ACP7 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs1329833442, COSV100488595; called by muse, mutect2, varscan2
- ACTA2 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as CM156147, COSV99827228; called by muse, mutect2, varscan2
- ACTN3 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV101557878; called by muse, mutect2, varscan2
- ACTRT1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1235343335, COSV100947725; called by muse, mutect2
- ACTRT1 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64419913; called by muse, mutect2
- ADAM19 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99978222; called by muse, mutect2, varscan2
- ADAMTS16 | c.941A>T p.Y314F | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99942608; called by muse, mutect2, varscan2
- ADAMTS20 | c.3827A>T p.Q1276L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV67128014; called by muse, mutect2, varscan2
- ADAMTS20 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101240175; called by muse, mutect2
- ADGRG4 | c.1862C>A p.T621N | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV99796456; called by muse, mutect2
- ADNP2 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100081152; called by muse, mutect2, varscan2
- AFAP1L1 | c.2097G>T p.Q699H | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99696083; called by muse, mutect2, varscan2
- AFF2 | c.3195T>A p.F1065L | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99665866; called by muse, mutect2
- ANKLE2 | c.1140G>A p.M380I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100514327; called by muse, mutect2, varscan2
- ANO4 | c.1311G>T p.W437C (on ENST00000392977 / NM_001286615.2; = p.W402C on NM_178826.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100153592, COSV54614380; called by muse, mutect2, varscan2
- APCDD1 | c.149C>G p.S50* | Nonsense Mutation (SNP) | VAF 12/136 reads (9%) | catalogued as COSV100790008; called by muse, mutect2
- ARHGEF28 | c.787G>T p.A263S | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT tolerated (0.97); PolyPhen benign (0.009); catalogued as COSV99709938; called by muse, mutect2, varscan2
- ASIC5 | c.152A>T p.H51L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV101539788; called by muse, mutect2, varscan2
- ASPN | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV100978671; called by muse, mutect2, varscan2
- ATL1 | c.862+1G>A p.X288_splice | Splice Site (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100613276; called by muse, mutect2
- ATP6V1B2 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV99369581; called by muse, mutect2
- ATP6V1E2 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as COSV100120807; called by muse, mutect2, varscan2
- ATXN2L | c.753G>T p.W251C | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100295037; called by muse, mutect2, varscan2
- BAZ2A | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs767981157, COSV51640463; called by muse, mutect2, varscan2
- BAZ2B | c.1888G>A p.D630N | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.761); catalogued as COSV100600927; called by muse, mutect2, varscan2
- BRCA1 | c.4935G>T p.R1645S | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV100524887; called by muse, mutect2, varscan2
- C14orf28 | c.785A>T p.E262V | Missense Mutation (SNP) | VAF 17/145 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100290336; called by muse, mutect2, varscan2
- C2CD3 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.316); catalogued as COSV100487280; called by muse, mutect2
- C7orf25 | c.946G>C p.D316H | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100623661; called by muse, mutect2, varscan2
- C8B | c.1083C>A p.N361K | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV100980883; called by muse, mutect2
- CACNA1E | c.136A>T p.R46W | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100704792; called by muse, mutect2, varscan2
- CACNA1S | c.3555T>G p.F1185L | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100755308; called by muse, mutect2, varscan2
- CACNG5 | c.231T>A p.Y77* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV99400793; called by muse, mutect2, varscan2
- CASD1 | c.2351G>T p.G784V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.259); catalogued as COSV99802976; called by muse, mutect2
- CATSPERD | c.787C>A p.L263M | Missense Mutation (SNP) | VAF 69/211 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101062769; called by muse, mutect2, varscan2
- CBX2 | c.1517C>T p.T506I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99490990; called by mutect2, varscan2
- CCDC148 | c.427C>G p.H143D | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99321304; called by muse, mutect2, varscan2
- CCDC85A | c.1644G>C p.Q548H | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as COSV101339537; called by muse, mutect2, varscan2
- CCNA1 | c.1080G>T p.R360S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV55224575; called by muse, mutect2, varscan2
- CD226 | c.234G>C p.R78S | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99711463; called by muse, mutect2, varscan2
- CD2BP2 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99977208; called by muse, mutect2, varscan2
- CDC6 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99266658; called by muse, mutect2, varscan2
- CDH10 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100052836; called by muse, mutect2, varscan2
- CDH5 | c.1331C>T p.T444I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.349); catalogued as COSV100439403; called by muse, mutect2, varscan2
- CEMIP2 | c.892C>T p.Q298* | Nonsense Mutation (SNP) | VAF 13/105 reads (12%) | catalogued as COSV100987493; called by muse, mutect2, varscan2
- CHD3 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV100391587; called by muse, mutect2, varscan2
- CHRM2 | c.363G>T p.R121S | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751591780, COSV100281774; called by muse, mutect2, varscan2
- CIBAR1 | c.458G>C p.R153T | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV100844716; called by muse, mutect2
- CILK1 | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV100607983; called by muse, mutect2
- COL11A1 | c.3583G>T p.G1195C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100617889; called by muse, mutect2, varscan2
- COL12A1 | c.5041G>T p.D1681Y | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100486379; called by muse, mutect2, varscan2
- COL25A1 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 80/299 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101211619; called by muse, mutect2, varscan2
- COL2A1 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100477315; called by muse, mutect2
- COL2A1 | c.973C>G p.P325A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV100477320; called by muse, mutect2, varscan2
- COL7A1 | c.6434C>T p.P2145L | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs937174861, COSV60401284; called by muse, mutect2, varscan2
- CORIN | c.938G>T p.C313F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99904303; called by muse, mutect2, varscan2
- CSMD1 | c.7809C>G p.C2603W (on ENST00000520002; = p.C2602W on NM_033225.6) | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100152885; called by muse, mutect2, varscan2
- CSMD3 | c.8783G>T p.C2928F (on ENST00000297405 / NM_001363185.1; = p.C2759F on NM_052900.3) | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99845318; called by muse, mutect2, varscan2
- CTNNA3 | c.1519C>A p.L507I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV65552225; called by muse, varscan2
- CTNNA3 | c.1518C>A p.F506L | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65627569, COSV65628203; called by muse, varscan2
- CTNND2 | c.2561T>C p.L854P | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100480356; called by muse, mutect2
- CYP46A1 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs757381529, COSV99952405; called by muse, mutect2, varscan2
- DCHS1 | c.5363G>T p.R1788L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100202495, COSV55034050; called by muse, mutect2, varscan2
- DDX53 | c.198C>G p.Y66* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100029070; called by muse, mutect2, varscan2
- DEPDC1 | c.1602G>T p.M534I | Missense Mutation (SNP) | VAF 64/214 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100920458, COSV63959487; called by muse, mutect2, varscan2
- DHX38 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99194543; called by muse, mutect2, varscan2
- DISP1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as COSV99452025; called by muse, mutect2, varscan2
- DNAH10 | c.5674G>T p.A1892S (on ENST00000409039; = p.A1831S on NM_207437.3) | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs761217087, COSV101292554, COSV69003535; called by muse, mutect2, varscan2
- DNAH7 | c.793A>T p.S265C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.198); catalogued as COSV100417081; called by muse, mutect2, varscan2
- DNTTIP1 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as rs765900526, COSV101010052; called by muse, mutect2, varscan2
- DOCK10 | c.4822T>G p.L1608V | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51348149; called by muse, mutect2, varscan2
- DPF3 | c.856G>T p.D286Y | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100818670; called by muse, mutect2
- DSPP | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV56810823; called by muse, mutect2
- EPHA10 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100140117; called by muse, mutect2, varscan2
- EPHA5 | c.182-2A>T p.X61_splice | Splice Site (SNP) | VAF 11/56 reads (20%) | catalogued as COSV99900785; called by muse, mutect2, varscan2
- EPHA7 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65169257; called by muse, mutect2, varscan2
- EPHB6 | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100844409; called by muse, mutect2, varscan2
- EPN1 | c.1204G>T p.D402Y (on ENST00000270460 / NM_001321263.1; = p.D376Y on NM_013333.3) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99322301; called by muse, mutect2, varscan2
- EPN3 | c.608G>T p.R203L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV52138771, COSV99277312; called by muse, mutect2, varscan2
- ERICH3 | c.1851G>T p.R617S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100445423; called by muse, mutect2, varscan2
- ERN1 | c.1381A>T p.I461F | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as COSV101458528; called by muse, mutect2, varscan2
- ESYT1 | c.2854C>A p.P952T | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV99920230; called by muse, mutect2, varscan2
- FAM214A | c.2871A>G p.I957M | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99958436; called by muse, mutect2, varscan2
- FAM83B | c.1729C>A p.P577T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.255); catalogued as rs1352744650, COSV100174913; called by muse, mutect2, varscan2
- FHOD3 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99942568; called by muse, mutect2, varscan2
- FIGNL1 | c.2017G>T p.G673* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100794944; called by muse, mutect2
- FUBP3 | c.840G>C p.Q280H | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100156290; called by muse, mutect2, varscan2
- GAB2 | c.139G>T p.E47* (on ENST00000361507 / NM_080491.3; = p.E9* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 14/152 reads (9%) | catalogued as COSV60871011; called by muse, mutect2
- GABRG2 | c.299G>T p.S100I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100729814; called by muse, mutect2, varscan2
- GAN | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as COSV101634026; called by muse, mutect2, varscan2
- GBF1 | c.2674A>G p.T892A (on ENST00000369983 / NM_001377137.1; = p.T891A on NM_004193.3) | Missense Mutation (SNP) | VAF 16/114 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100890641; called by muse, mutect2, varscan2
- GDAP2 | c.878A>G p.D293G | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101032143; called by muse, mutect2, varscan2
- GGA3 | c.607G>T p.E203* (on ENST00000537686 / NM_138619.4; = p.E170* on NM_014001.5) | Nonsense Mutation (SNP) | VAF 16/178 reads (9%) | catalogued as COSV99822295; called by muse, mutect2
- GJA8 | c.941G>T p.R314L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.165); catalogued as COSV99569646; called by muse, mutect2, varscan2
- GJC3 | c.836C>A p.A279D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.665); catalogued as COSV100458500, COSV57210829; called by muse, mutect2
- GJD4 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs1193854854, COSV100397223; called by muse, mutect2
- GPAT4 | c.872A>C p.E291A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101214108; called by muse, mutect2, varscan2
- GPR135 | c.1097C>A p.S366* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | catalogued as COSV101229343; called by muse, mutect2, varscan2
- GPR158 | c.3454C>T p.R1152C | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs368132351, COSV100893879; called by muse, mutect2, varscan2
- GPR50 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs376836037, COSV99505537, COSV99506516; called by muse, mutect2, varscan2
- GPR78 | c.746C>A p.T249N | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV101224036; called by muse, mutect2, varscan2
- GRIN2B | c.2983G>A p.G995S | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.705); catalogued as COSV101663166, COSV74207397; called by muse, mutect2, varscan2
- GUCY2F | c.2868G>C p.M956I | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99485535; called by muse, mutect2, varscan2
- HADHB | c.1048C>A p.Q350K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100502132; called by muse, mutect2, varscan2
- HCRTR2 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100904571; called by muse, mutect2, varscan2
- HDX | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.991); catalogued as COSV52980519, COSV99947925; called by muse, mutect2, varscan2
- HEPH | c.1286G>T p.W429L (on ENST00000343002; = p.W162L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.084); catalogued as COSV100295065, COSV100295561; called by muse, mutect2
- HPCAL4 | c.549G>T p.L183F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.284); catalogued as COSV100864812; called by muse, mutect2, varscan2
- HYAL4 | c.1100C>A p.A367D | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99772426; called by muse, mutect2, varscan2
- IL17F | c.215G>T p.R72L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV100277289; called by muse, mutect2, varscan2
- INSRR | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100947993; called by muse, mutect2, varscan2
- INTS1 | c.1776G>T p.W592C | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101248264; called by muse, mutect2, varscan2
- INTS5 | c.2354A>T p.H785L | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV100399783; called by muse, mutect2, varscan2
- INTS6L | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV100878256; called by muse, mutect2, varscan2
- ITLN2 | c.874T>C p.C292R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100600750; called by muse, mutect2, varscan2
- JMJD1C | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101232459; called by muse, mutect2, varscan2
- JPH3 | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as rs373143340, COSV99413901; called by muse, mutect2, varscan2
- KCNH8 | c.2899G>T p.G967W | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV100110893; called by muse, mutect2, varscan2
- KIAA1109 | c.9521G>A p.R3174K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV99172798; called by muse, mutect2, varscan2
- KIAA1549 | c.2665G>T p.G889C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.584); catalogued as COSV54306766, COSV99651769; called by muse, mutect2, varscan2
- KIF26A | c.4375C>A p.P1459T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.038); catalogued as rs771349955, COSV100181499; called by muse, mutect2, varscan2
- KIF5A | c.2431A>T p.K811* | Nonsense Mutation (SNP) | VAF 20/454 reads (4%) | catalogued as COSV99673472; called by muse, mutect2
- KLHL1 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100917995, COSV64770281; called by muse, mutect2, varscan2
- KLHL1 | c.1015-1G>T p.X339_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV64771130, COSV64776196; called by muse, mutect2, varscan2
- KMT2D | c.14334A>T p.K4778N | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV99985274, COSV99987462; called by muse, mutect2, varscan2
- KRT33B | c.1076T>G p.L359R | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99290823; called by muse, mutect2, varscan2
- LGALS9 | c.576+1G>T p.X192_splice (on ENST00000395473 / NM_009587.3; = p.X160_splice on NM_002308.4) | Splice Site (SNP) | VAF 49/301 reads (16%) | catalogued as COSV100119521; called by muse, mutect2, varscan2
- LHX9 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV100436041; called by muse, mutect2, varscan2
- LMO2 | c.444C>G p.I148M (on ENST00000395833 / NM_001142315.2; = p.I217M on NM_005574.4) | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99137889; called by muse, mutect2
- MAGEB6B | c.230C>T p.A77V | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1377092332; called by muse, mutect2, varscan2
- MAP4 | c.3271G>T p.G1091C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99276143; called by muse, mutect2
- MCF2L2 | c.2225T>A p.L742Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100193727; called by mutect2, varscan2
- MCHR2 | c.981G>C p.K327N | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99912409, COSV99912563; called by muse, mutect2, varscan2
- MEIOB | c.932T>C p.L311S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV100379930; called by muse, mutect2, varscan2
- MIA2 | c.1568-1G>A p.X523_splice | Splice Site (SNP) | VAF 11/92 reads (12%) | catalogued as COSV99696691, COSV99696899; called by muse, mutect2, varscan2
- MMRN1 | c.17T>A p.L6* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV99307678; called by muse, mutect2, varscan2
- MRGPRF | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.069); catalogued as COSV100307915; called by muse, mutect2, varscan2
- MROH9 | c.539C>A p.S180Y | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.729); catalogued as COSV63010296; called by muse, mutect2, varscan2
- MROH9 | c.1609G>A p.D537N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); catalogued as COSV100882733, COSV100882997; called by muse, mutect2
- MRPL28 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as COSV99170786; called by muse, mutect2, varscan2
- MS4A2 | c.406G>T p.A136S | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as COSV99627043; called by muse, mutect2, varscan2
- MS4A6A | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as COSV100124502, COSV100124941, COSV60618722; called by muse, mutect2, varscan2
- MTO1 | c.820A>C p.I274L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.02); catalogued as COSV100940526; called by muse, mutect2, varscan2
- MTREX | c.1381C>T p.P461S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100044451; called by muse, mutect2
- MYH13 | c.3931G>T p.A1311S | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.88); PolyPhen benign (0.034); catalogued as COSV99355175; called by muse, mutect2, varscan2
- MYO5B | c.3264G>T p.M1088I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99546107; called by muse, mutect2, varscan2
- NCK2 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51888042; called by muse, mutect2, varscan2
- NCOR1 | c.2197C>G p.P733A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99251722; called by muse, mutect2, varscan2
- NFATC3 | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.949); catalogued as COSV100285641; called by muse, mutect2, varscan2
- NGDN | c.85A>T p.T29S | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV101238913; called by muse, mutect2, varscan2
- NLGN2 | c.926G>T p.R309L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.066); catalogued as COSV100259576; called by muse, mutect2, varscan2
- NOBOX | c.869T>G p.I290R | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99779637; called by muse, mutect2, varscan2
- NOM1 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1394508735, COSV99315995; called by muse, mutect2
- NPHS2 | c.1091C>G p.P364R | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.302); catalogued as COSV100858204, COSV62635214, COSV62636715; called by muse, mutect2
- OR10Q1 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100372372; called by muse, mutect2, varscan2
- OR1N1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.878); catalogued as COSV100509707; called by muse, mutect2
- OR4D11 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as rs781050742, COSV57585880; called by muse, mutect2, varscan2
- OR4K17 | c.215C>A p.T72N | Missense Mutation (SNP) | VAF 46/494 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV100210780; called by muse, mutect2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 75/591 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by muse, mutect2, varscan2
- OR52E6 | c.752C>A p.A251D | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100259507; called by muse, mutect2, varscan2
- OR52E6 | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 28/194 reads (14%) | catalogued as COSV100259511; called by muse, mutect2, varscan2
- OR5AS1 | c.547C>A p.P183T | Missense Mutation (SNP) | VAF 33/418 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1351853859, COSV100546288, COSV57982204; called by muse, mutect2
- OR5L2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101004400; called by muse, mutect2
- OR6F1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100129405; called by muse, mutect2, varscan2
- OR8U1 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 43/202 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164087; called by muse, mutect2, varscan2
- P2RY4 | c.928G>T p.G310W | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100997047; called by muse, mutect2, varscan2
- PABPC5 | c.957G>T p.K319N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as COSV100442644; called by muse, mutect2, varscan2
- PAK5 | c.346G>T p.G116C | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV100781635, COSV62024463; called by muse, mutect2, varscan2
- PAX8 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99640014; called by muse, mutect2
- PCDHA4 | c.1345A>T p.N449Y | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100793692; called by muse, mutect2, varscan2
- PCDHB10 | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); catalogued as rs1288370484, COSV99504914; called by muse, mutect2, varscan2
- PDS5A | c.3163G>C p.E1055Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV100337532, COSV57825000; called by muse, mutect2
- PDZRN4 | c.1507T>A p.L503I (on ENST00000402685 / NM_001164595.2; = p.L245I on NM_013377.4) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.437); catalogued as COSV100115309; called by muse, mutect2, varscan2
- PER3 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV100728459; called by muse, mutect2, varscan2
- PGA5 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100409377; called by muse, mutect2
- PGR | c.2284G>T p.G762C | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99678858; called by muse, mutect2, varscan2
- PHF14 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.202); catalogued as rs1187854128, COSV101301852; called by muse, mutect2, varscan2
- PHF8 | c.2227G>T p.A743S (on ENST00000357988 / NM_001184896.1; = p.A707S on NM_015107.3) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.81); PolyPhen benign (0.009); catalogued as COSV100154719; called by muse, mutect2
- PIP4K2C | c.175-1G>A p.X59_splice | Splice Site (SNP) | VAF 7/141 reads (5%) | catalogued as COSV100724016; called by muse, mutect2
- PITHD1 | c.544C>T p.H182Y | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1333422635, COSV99862216; called by muse, mutect2, varscan2
- PJA2 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV100754514; called by muse, mutect2
- PKHD1 | c.10532G>T p.G3511V | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.216); catalogued as COSV100945178; called by muse, mutect2, varscan2
- PKN2 | c.752G>A p.R251K | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV100281722; called by muse, mutect2
- PKP2 | c.1322G>T p.R441L | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV50732952, COSV99296981; called by muse, mutect2, varscan2
- PODN | c.391G>T p.G131C (on ENST00000395871; = p.G83C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV100439777; called by muse, mutect2, varscan2
- PPP2R1A | c.1130G>T p.C377F | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV59044854; called by muse, mutect2, varscan2
- PRELID3B | c.461G>T p.S154I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99718205; called by muse, mutect2, varscan2
- PRUNE2 | c.5839G>A p.D1947N | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV100945047; called by muse, mutect2
- PTCHD4 | c.841G>T p.G281W | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100261476; called by muse, mutect2, varscan2
- PTPRA | c.416-1G>A p.X139_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99399809, COSV99400501; called by muse, mutect2, varscan2
- PTPRC | c.3331-1G>T p.X1111_splice | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV100723047; called by muse, mutect2
- PTPRT | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100629974; called by muse, mutect2, varscan2
- RALGPS1 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99402429; called by muse, mutect2, varscan2
- RBL1 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV100727268; called by muse, mutect2, varscan2
- RECQL4 | c.3094G>C p.E1032Q | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as COSV100020803; called by muse, mutect2, varscan2
- RIBC1 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV99395074; called by mutect2, varscan2
- RPUSD3 | c.789G>A p.M263I | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs921232881, COSV100047800; called by muse, mutect2, varscan2
- RUBCNL | c.102C>A p.N34K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as COSV100529336; called by muse, varscan2
- RUSF1 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100393382; called by muse, mutect2, varscan2
- SAMD4A | c.1843G>A p.G615S | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.287); catalogued as COSV99200800; called by muse, mutect2, varscan2
- SCEL | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100583165; called by muse, mutect2, varscan2
- SDF2 | c.563G>A p.W188* | Nonsense Mutation (SNP) | VAF 21/126 reads (17%) | catalogued as rs1353530469, COSV99897999; called by muse, mutect2, varscan2
- SERPINI1 | c.31G>T p.V11F | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV99855356; called by muse, mutect2
- SETBP1 | c.3803G>T p.G1268V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.067); catalogued as COSV99954630; called by muse, mutect2, varscan2
- SEZ6L | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV99962780; called by muse, mutect2, varscan2
- SGIP1 | c.1508C>G p.A503G | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52770104, COSV52770638, COSV99392643; called by muse, mutect2, varscan2
- SHISA2 | c.455G>T p.S152I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV100096600; called by muse, mutect2, varscan2
- SLC14A2 | c.2695T>A p.Y899N | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as COSV99676047; called by muse, mutect2, varscan2
- SLC22A12 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100327843; called by muse, mutect2, varscan2
- SLC27A6 | c.365G>A p.W122* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99323376; called by mutect2, varscan2
- SLC6A15 | c.289+1G>T p.X97_splice | Splice Site (SNP) | VAF 8/63 reads (13%) | catalogued as COSV99881430; called by muse, mutect2, varscan2
- SLITRK5 | c.1849G>T p.D617Y | Missense Mutation (SNP) | VAF 29/159 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV61523670, COSV61523777; called by muse, mutect2, varscan2
- SMOC1 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100734355, COSV100734769; called by muse, mutect2
- SORL1 | c.4286G>T p.G1429V | Missense Mutation (SNP) | VAF 79/210 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99495216; called by muse, mutect2, varscan2
- SOX3 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as COSV100983752; called by muse, mutect2, varscan2
- SPATC1 | c.804C>A p.D268E | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV101085256; called by muse, mutect2, varscan2
- SPHKAP | c.4444C>A p.H1482N | Missense Mutation (SNP) | VAF 6/180 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV60887529; called by muse, mutect2
- SPIN2B | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.441); catalogued as COSV99328200; called by muse, mutect2, varscan2
- SPOCK2 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV100436471; called by muse, mutect2, varscan2
- SPRR1A | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.1); catalogued as COSV100201100; called by muse, mutect2, varscan2
- SPTLC3 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100983270; called by muse, mutect2, varscan2
- STARD7 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV100474877; called by muse, mutect2, varscan2
- TAS1R2 | c.216G>A p.M72I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as rs749486871, COSV100946341; called by muse, mutect2, varscan2
- TBCE | c.336G>C p.E112D | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.72); catalogued as COSV100783231; called by muse, mutect2, varscan2
- TBX3 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.366); catalogued as COSV99984063; called by muse, mutect2, varscan2
- THOC1 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99863579; called by muse, mutect2, varscan2
- TKTL2 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 35/158 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.053); catalogued as rs375870748; called by muse, mutect2, varscan2
- TMEM135 | c.629G>T p.R210I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100450083; called by muse, mutect2, varscan2
- TMPRSS11E | c.826T>A p.Y276N | Missense Mutation (SNP) | VAF 57/461 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV100542190, COSV100542495; called by muse, mutect2, varscan2
- TMPRSS15 | c.727T>A p.Y243N | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99519100; called by muse, mutect2, varscan2
- TNN | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99512798; called by muse, mutect2, varscan2
- TRANK1 | c.5209C>T p.H1737Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs1394536991, COSV100084480, COSV100084667; called by muse, mutect2
- TRIL | c.398T>A p.L133Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538943; called by muse, mutect2, varscan2
- TRIM43 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.278); catalogued as COSV99720057; called by muse, mutect2, varscan2
- TRMT5 | c.442C>G p.H148D | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV50788591; called by muse, mutect2, varscan2
- TSHB | c.338G>A p.S113N | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.724); catalogued as COSV99859098; called by muse, mutect2, varscan2
- TSPAN17 | c.376A>T p.N126Y | Missense Mutation (SNP) | VAF 24/187 reads (13%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.687); catalogued as COSV100024855; called by muse, mutect2, varscan2
- UBE3A | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as COSV99217773; called by muse, mutect2, varscan2
- UQCC1 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.033); catalogued as COSV100568810, COSV62902596; called by muse, mutect2, varscan2
- USH2A | c.9659G>T p.G3220V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100241178; called by muse, mutect2, varscan2
- USH2A | c.7853G>T p.W2618L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as CM165986, COSV100241181; called by muse, mutect2
- USP19 | c.191C>T p.S64L | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100026440; called by muse, mutect2
- UTP6 | c.1738G>C p.E580Q | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV99912091; called by muse, mutect2
- VCAN | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99427059; called by muse, mutect2, varscan2
- VDR | c.117G>C p.M39I | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV99968955; called by muse, mutect2, varscan2
- VHL | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1057517560, CM106926, COSV56543105, COSV56564700, COSV99846812; ClinVar: uncertain significance; called by muse, mutect2
- WASF3 | c.510A>T p.E170D | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100099362; called by muse, mutect2, varscan2
- WSCD2 | c.948T>A p.S316R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99775139; called by muse, mutect2, varscan2
- ZACN | c.655T>A p.C219S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV100135654; called by muse, mutect2
- ZC3HAV1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 31/177 reads (18%) | catalogued as rs781488748, COSV99649004; called by muse, mutect2, varscan2
- ZFP90 | c.1384A>T p.I462F | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV101238804; called by muse, mutect2, varscan2
- ZIC1 | c.944G>C p.R315P | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51551053; called by muse, mutect2
- ZKSCAN1 | c.819G>T p.E273D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100164345; called by muse, mutect2, varscan2
- ZNF114 | c.179C>A p.P60Q | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs377746989, COSV100252141; called by muse, mutect2, varscan2
- ZNF385D | c.634G>C p.A212P | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV99876095; called by muse, mutect2, varscan2
- ZNF574 | c.464A>T p.K155M | Missense Mutation (SNP) | VAF 39/118 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.157); catalogued as COSV99726433; called by muse, mutect2, varscan2
- ZNF667 | c.963A>C p.Q321H | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV99410880; called by muse, mutect2, varscan2
- ZNF672 | c.1303G>T p.A435S | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV100129381; called by muse, mutect2
- ZNF700 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 21/71 reads (30%) | catalogued as COSV99039032, COSV99583757; called by muse, mutect2, varscan2
- ZNF800 | c.408A>G p.I136M | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99758154; called by muse, mutect2
- ZSCAN2 | c.993G>C p.E331D | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV100306909, COSV100306958; called by muse, mutect2, varscan2
- ABHD17B | c.403G>T p.G135W | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS12 | c.861del p.I287Mfs*22 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | called by mutect2, pindel, varscan2
- ARMH4 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2
- CDH12 | c.1953del p.D652Tfs*27 | Frame Shift Del (DEL) | VAF 18/125 reads (14%) | called by mutect2, pindel, varscan2
- CSMD2 | c.4308del p.S1437Afs*13 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, pindel, varscan2
- CTNND2 | c.532del p.L178Wfs*154 | Frame Shift Del (DEL) | VAF 22/150 reads (15%) | called by mutect2, pindel*, varscan2
- FKBP5 | c.1111_1131del p.K371_V377del | In Frame Del (DEL) | VAF 20/207 reads (10%) | called by mutect2, pindel*
- HK3 | c.1933del p.E645Kfs*11 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | called by pindel, varscan2
- LRRC8C | c.2208dup p.G737Wfs*26 | Frame Shift Ins (INS) | VAF 8/75 reads (11%) | called by mutect2, pindel, varscan2
- LRRK2 | c.3926_3933del p.K1309Rfs*3 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- OR10X1 | c.778del p.H260Tfs*6 | Frame Shift Del (DEL) | VAF 30/186 reads (16%) | called by mutect2, pindel, varscan2
- OR2T35 | c.878G>T p.R293M | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- POTEF | c.2539C>A p.R847S | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- PRAMEF15 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2
- SATB2 | c.1612del p.L538Sfs*8 | Frame Shift Del (DEL) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.2752C>G p.Q918E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.082); called by mutect2, varscan2
- TNXB | c.2012T>A p.V671E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- TREML2 | c.401_409del p.P134_T136del | In Frame Del (DEL) | VAF 11/49 reads (22%) | called by mutect2, pindel, varscan2
- ZNF33B | c.1591G>T p.G531W | Missense Mutation (SNP) | VAF 19/145 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANAPC2 | c.648G>A p.L216= | Silent (SNP) | VAF 15/116 reads (13%) | catalogued as COSV100119215; called by muse, mutect2, varscan2
- ANK2 | c.2004G>T p.L668= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100003740; called by muse, mutect2, varscan2
- ATP13A2 | c.2478C>T p.S826= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs147611385; called by muse, mutect2, varscan2
- BPIFB4 | c.267C>T p.H89= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV100971641; called by muse, mutect2, varscan2
- BRSK1 | c.1302T>C p.S434= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100474545; called by muse, mutect2, varscan2
- C3orf38 | c.861G>T p.P287= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100007483; called by muse, mutect2, varscan2
- CCL16 | c.27T>A p.S9= | Silent (SNP) | VAF 4/29 reads (14%) | called by muse, mutect2, varscan2
- CELA1 | c.507C>A p.P169= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV99530259; called by mutect2, varscan2
- CHRM3 | c.390C>T p.I130= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV99699339; called by muse, mutect2, varscan2
- CKAP5 | c.3654G>A p.Q1218= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100371320; called by muse, mutect2, varscan2
- DSPP | c.15A>T p.T5= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV99217868; called by muse, mutect2
- EP300 | c.513G>T p.A171= | Silent (SNP) | VAF 18/116 reads (16%) | catalogued as COSV99609576; called by muse, mutect2, varscan2
- FAM153B | c.531T>C p.V177= (on ENST00000253490; = p.V100= on NM_001265615.1) | Silent (SNP) | VAF 14/206 reads (7%) | catalogued as COSV99499112; called by muse, varscan2
- FAT3 | c.4413G>A p.E1471= | Silent (SNP) | VAF 43/175 reads (25%) | catalogued as COSV99970148; called by muse, mutect2, varscan2
- FBXL7 | c.1350C>A p.A450= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV100310660; called by muse, mutect2, varscan2
- GAB2 | c.138G>A p.L46= (on ENST00000361507 / NM_080491.3; = p.L8= on NM_012296.3) | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV100416766; called by muse, mutect2
- GALNT17 | c.483G>A p.V161= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100355773; called by muse, mutect2, varscan2
- GRID2 | c.2748G>T p.L916= | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV56242150; called by muse, mutect2, varscan2
- HLTF | c.2088G>T p.G696= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100027057; called by muse, mutect2, varscan2
- IGKV3-11 | c.162C>T p.A54= | Silent (SNP) | VAF 23/114 reads (20%) | catalogued as rs759074719; called by muse, mutect2, varscan2
- ITIH1 | c.2595C>T p.L865= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as COSV99835583; called by muse, mutect2, varscan2
- JMJD1C | c.5115C>A p.V1705= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100550791; called by muse, mutect2, varscan2
- KCNA5 | c.1221G>T p.V407= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV99364137; called by muse, mutect2, varscan2
- KCNK18 | c.378C>A p.T126= | Silent (SNP) | VAF 78/277 reads (28%) | catalogued as COSV100572119; called by muse, mutect2, varscan2
- KLHDC3 | c.720G>C p.R240= | Silent (SNP) | VAF 61/189 reads (32%) | catalogued as COSV55065289, COSV99763904; called by muse, mutect2, varscan2
- KLHL13 | c.996G>A p.R332= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV99452407; called by muse, mutect2, varscan2
- KRTAP26-1 | c.150C>T p.T50= | Silent (SNP) | VAF 23/185 reads (12%) | catalogued as rs1234317644, COSV100860471, COSV62129011; called by muse, mutect2, varscan2
- LRRK1 | c.5229T>C p.S1743= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99442661; called by mutect2, varscan2
- MAML1 | c.2862G>T p.G954= | Silent (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99483338; called by muse, mutect2
- MAPT | c.957G>T p.R319= (on ENST00000262410 / NM_001377265.1; = p.R244= on NM_016835.4) | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99291197; called by muse, mutect2, varscan2
- MDGA2 | c.2706T>A p.T902= (on ENST00000399232 / NM_001113498.2; = p.T604= on NM_182830.4) | Silent (SNP) | VAF 16/138 reads (12%) | catalogued as rs773702663, COSV100638169; called by muse, mutect2, varscan2
- MTOR | c.4920G>T p.R1640= | Silent (SNP) | VAF 20/226 reads (9%) | catalogued as COSV100816611; called by muse, mutect2
- MUC17 | c.7749C>A p.T2583= | Silent (SNP) | VAF 62/651 reads (10%) | called by muse, mutect2
- MXRA5 | c.3201A>G p.L1067= | Silent (SNP) | VAF 17/102 reads (17%) | catalogued as COSV99478846; called by muse, mutect2, varscan2
- MYH4 | c.2274C>A p.T758= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99702064; called by muse, mutect2, varscan2
- MYLK | c.156C>T p.F52= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs200095645, COSV60604762; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYOC | c.1227G>A p.E409= | Silent (SNP) | VAF 33/168 reads (20%) | catalogued as rs536180276, COSV50676523; called by muse, mutect2, varscan2
- NTSR1 | c.352C>T p.L118= | Silent (SNP) | VAF 6/53 reads (11%) | catalogued as COSV100980702; called by muse, mutect2, varscan2
- OLFM3 | c.591G>A p.E197= (on ENST00000338858 / NM_001288821.1; = p.E177= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1364852960, COSV100129972; called by muse, mutect2, varscan2
- OR2W3 | c.501C>A p.P167= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV100831768, COSV64457522; called by muse, mutect2, varscan2
- OR51A2 | c.138C>A p.T46= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV100985087; called by muse, mutect2, varscan2
- OR5M8 | c.114G>T p.V38= | Silent (SNP) | VAF 20/191 reads (10%) | catalogued as COSV100510758; called by muse, mutect2, varscan2
- OR5R1 | c.549C>T p.P183= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV100393512, COSV100393558; called by muse, mutect2, varscan2
- PARP12 | c.639G>A p.L213= | Silent (SNP) | VAF 30/185 reads (16%) | catalogued as COSV99694239; called by muse, mutect2, varscan2
- PAX1 | c.1377C>A p.P459= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV101270372; called by muse, mutect2, varscan2
- PCDHA11 | c.1533G>T p.A511= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as COSV100253691; called by muse, mutect2, varscan2
- PCDHA8 | c.2076G>T p.A692= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV65325006, COSV65331587; called by muse, mutect2, varscan2
- PCDHGA10 | c.1503G>A p.Q501= | Silent (SNP) | VAF 33/188 reads (18%) | catalogued as rs1276367800, COSV99545309; called by muse, mutect2, varscan2
- PGM2 | c.1053G>T p.L351= | Silent (SNP) | VAF 35/171 reads (20%) | catalogued as COSV101126631; called by muse, mutect2, varscan2
- PIGO | c.1716C>A p.A572= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99956903; called by muse, mutect2, varscan2
- PIK3R5 | c.2454C>T p.C818= | Silent (SNP) | VAF 6/84 reads (7%) | catalogued as COSV99353759; called by muse, mutect2
- PJA2 | c.819T>C p.T273= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV100754516; called by muse, mutect2
- PKHD1 | c.207G>T p.V69= | Silent (SNP) | VAF 35/165 reads (21%) | catalogued as COSV100584324; called by muse, mutect2, varscan2
- PRAMEF19 | c.1425G>T p.R475= | Silent (SNP) | VAF 41/167 reads (25%) | called by muse, mutect2, varscan2
- RHBDD2 | c.504G>T p.P168= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs377724977; called by muse, mutect2, varscan2
- ROR1 | c.2586G>A p.S862= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs573453757, COSV100935517; called by muse, mutect2, varscan2
- SIM1 | c.1774C>T p.L592= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs143641343, COSV99492687, COSV99492969; called by muse, mutect2, varscan2
- SLC10A5 | c.160C>A p.R54= | Silent (SNP) | VAF 33/165 reads (20%) | catalogued as COSV101594267; called by muse, mutect2, varscan2
- SLC17A4 | c.381C>A p.P127= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV100930659; called by muse, mutect2, varscan2
- SLC25A43 | c.318G>A p.Q106= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV99474673; called by muse, mutect2
- SLC36A2 | c.1113C>A p.S371= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100079372; called by muse, mutect2, varscan2
- SLC51A | c.1014C>G p.L338= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV99492410; called by muse, mutect2, varscan2
- SMG5 | c.2835C>T p.L945= | Silent (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99431555; called by muse, mutect2
- SPTBN1 | c.4146C>T p.A1382= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as rs775402962, COSV100443290; called by muse, mutect2, varscan2
- SUPT6H | c.1944G>T p.L648= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as COSV100112718; called by muse, mutect2
- SYT7 | c.294C>G p.T98= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as COSV99802083; called by muse, mutect2, varscan2
- TAS1R2 | c.1698C>T p.T566= | Silent (SNP) | VAF 5/81 reads (6%) | catalogued as COSV100946339; called by muse, mutect2
- TATDN2 | c.2238C>A p.L746= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV99813707; called by muse, mutect2
- TLR1 | c.1791G>T p.V597= | Silent (SNP) | VAF 90/239 reads (38%) | catalogued as COSV100458674; called by muse, mutect2, varscan2
- TMEM132B | c.120G>T p.T40= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as COSV54745118, COSV54746980; called by muse, mutect2, varscan2
- TMEM65 | c.321A>T p.P107= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99899337; called by muse, mutect2, varscan2
- TNFAIP6 | c.345C>A p.I115= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV54640518, COSV99694036; called by muse, mutect2
- TRERF1 | c.1323G>T p.L441= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100551453; called by muse, mutect2, varscan2
- TRPM4 | c.915G>T p.G305= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV99420744; called by muse, mutect2, varscan2
- TSHR | c.1059C>T p.Y353= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as rs771159611, COSV53323583, COSV53332401; called by muse, mutect2, varscan2
- TTC5 | c.426G>T p.L142= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV99351975; called by muse, mutect2, varscan2
- TTN | c.7938A>G p.P2646= (on ENST00000591111; = p.P2600= on NM_003319.4) | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as COSV100626581; called by muse, mutect2, varscan2
- TUBB4A | c.414G>T p.S138= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs1270650731, COSV51153419, COSV99900129; called by muse, mutect2, varscan2
- UBQLN4 | c.1236G>T p.T412= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV100849324, COSV100849360; called by muse, mutect2, varscan2
- UNC5C | c.2058C>T p.I686= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV101498010; called by muse, mutect2
- USH2A | c.1857G>T p.L619= | Silent (SNP) | VAF 17/88 reads (19%) | catalogued as COSV100241189; called by muse, mutect2, varscan2
- VANGL2 | c.24G>T p.S8= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV100925603; called by muse, mutect2
- WDR3 | c.387A>T p.T129= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100832342; called by muse, mutect2, varscan2
- ZFHX4 | c.4590G>A p.T1530= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs372556648, COSV50650286, COSV99266775; called by muse, mutect2, varscan2
- ZNF488 | c.687C>T p.L229= | Silent (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- FAM161A | c.1583+798C>G | Intron (SNP) | VAF 13/127 reads (10%) | catalogued as rs186972495, COSV100281479; called by muse, mutect2
- FHL1 | c.*16G>A | 3'UTR (SNP) | VAF 29/228 reads (13%) | catalogued as rs377071251, COSV100600831; called by muse, mutect2, varscan2
- MCF2L | c.169+6889G>A | Intron (SNP) | VAF 19/182 reads (10%) | catalogued as rs371178970; called by muse, mutect2, varscan2
- MIR892B | n.26C>A | RNA (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- OR3A4P | n.361G>A | RNA (SNP) | VAF 9/82 reads (11%) | catalogued as rs1314310310; called by mutect2, varscan2
- PARGP1 | n.765G>T | RNA (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- RTKN | c.111+2108del | Intron (DEL) | VAF 26/80 reads (33%) | called by mutect2, pindel, varscan2
- TTN | c.10360+4762C>G | Intron (SNP) | VAF 11/212 reads (5%) | catalogued as COSV100626580; called by muse, mutect2
